Somatic mutation profile of tumor specimen TCGA-A3-A6NN-01A (aliquot TCGA-A3-A6NN-01A-12D-A33K-10) from TCGA case TCGA-A3-A6NN, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 78.5 years (28,689 days).
Specimen TCGA-A3-A6NN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0036638-02ec-431a-8108-c958d7d6779e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-A6NN-10A (Blood Derived Normal), aliquot TCGA-A3-A6NN-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a10ae8ac-1b89-4ab6-8ce3-6aa024deb140

The open-access MAF lists 108 somatic variants for this specimen: 87 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 16, Frame Shift Del 7, Nonsense Mutation 5, In Frame Del 3, Frame Shift Ins 3, RNA 2, 5'UTR 2, Splice Region 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.05); catalogued as COSV99289142; called by muse, mutect2, varscan2
- ABCA12 | c.4244C>T p.T1415M (on ENST00000272895 / NM_173076.3; = p.T1097M on NM_015657.3) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as rs376792861, COSV55950925; called by muse, mutect2, varscan2
- ADGRE1 | c.941G>C p.S314T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV99165657; called by muse, mutect2, varscan2
- AGAP3 | c.2195A>G p.K732R (on ENST00000622464; = p.K768R on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101257344; called by muse, mutect2, varscan2
- ALG10B | c.835C>G p.R279G | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100439956; called by muse, mutect2, varscan2
- AMPD2 | c.875A>T p.E292V | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99858020; called by muse, mutect2, varscan2
- ANGPTL5 | c.705T>G p.N235K | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.857); catalogued as rs748045063, COSV100527927; called by muse, mutect2, varscan2
- ARMC4 | c.1426A>G p.M476V | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1269119470, COSV100537210; called by muse, mutect2
- ATM | c.2726C>T p.T909I | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs1555083259, COSV99591130; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXIN2 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV100196835; called by muse, mutect2, varscan2
- BIRC6 | c.8523A>T p.E2841D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV101428591; called by mutect2, varscan2
- C1orf226 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV100908146; called by muse, mutect2, varscan2
- C2CD2L | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760922364, COSV100371441; called by muse, mutect2, varscan2
- CASP8AP2 | c.5494T>A p.S1832T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99387347; called by muse, mutect2, varscan2
- CD27 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99869482; called by muse, mutect2, varscan2
- CEBPZ | c.1583T>G p.M528R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99135727; called by muse, mutect2, varscan2
- CELSR3 | c.8120C>T p.T2707I | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV99374514; called by muse, mutect2, varscan2
- CENPE | c.2252C>T p.S751F | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99478764; called by muse, mutect2, varscan2
- CTAGE1 | c.1637C>G p.S546* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV101194646; called by muse, mutect2, varscan2
- DHH | c.820T>A p.F274I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV99908903; called by muse, mutect2, varscan2
- DMD | c.5789G>A p.R1930H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759051688, COSV100821905, COSV63779129; called by mutect2, varscan2
- DNASE1L1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV99186195; called by muse, mutect2
- EBF1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58174482; called by muse, mutect2, varscan2
- EIF5B | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); catalogued as COSV99177680; called by muse, mutect2, varscan2
- FAM124A | c.1018C>T p.Q340* (on ENST00000322475 / NM_001242312.2; = p.Q376* on NM_145019.4) | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99696418; called by muse, mutect2, varscan2
- FBXL20 | c.831A>G p.I277M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1163666538, COSV99234582; called by muse, mutect2, varscan2
- FGL2 | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99592991; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.392T>C p.F131S | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100374571; called by muse, mutect2, varscan2
- GGN | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99287619; called by muse, mutect2, varscan2
- GGPS1 | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV99270555; called by muse, mutect2, varscan2
- GNB3 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV99301545; called by muse, mutect2, varscan2
- GUCA1A | c.126C>A p.F42L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.986); catalogued as COSV50004764; called by muse, mutect2, varscan2
- HNF4A | c.1192A>G p.M398V | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100291647; called by muse, mutect2, varscan2
- KAT2A | c.2180T>C p.L727P | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99288428; called by muse, mutect2
- KCNS2 | c.1366A>C p.M456L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV99751358; called by muse, mutect2, varscan2
- LRP2 | c.316A>C p.S106R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV99789759; called by muse, mutect2, varscan2
- LRRCC1 | c.1383A>C p.K461N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as COSV100835548; called by muse, mutect2, varscan2
- MDN1 | c.286G>C p.V96L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs769285696, COSV101021671; called by muse, mutect2, varscan2
- MTCH2 | c.272T>A p.V91D | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100207079; called by muse, mutect2, varscan2
- MUC16 | c.33598G>A p.V11200I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.162); catalogued as rs750455550, COSV101200789, COSV67487543; called by muse, mutect2
- NDST1 | c.1190A>T p.H397L | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99939025; called by muse, mutect2, varscan2
- NEK2 | c.1204A>G p.S402G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.014); catalogued as COSV100878733; called by muse, mutect2, varscan2
- NELFE | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100952832; called by muse, mutect2, varscan2
- NF1 | c.4601del p.R1534Hfs*40 (on ENST00000358273 / NM_001042492.3; = p.R1513Hfs*40 on NM_000267.3) | Frame Shift Del (DEL) | VAF 39/123 reads (32%) | catalogued as COSV62206694; called by mutect2, pindel, varscan2
- NFKBID | c.875C>G p.P292R (on ENST00000396901; = p.P444R on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs200193671, COSV100573252; called by muse, mutect2, varscan2
- NOMO3 | c.1949C>A p.T650N | Missense Mutation (SNP) | VAF 35/369 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV99530920; called by muse, mutect2, varscan2
- NPNT | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753563442, COSV99975359; called by muse, mutect2, varscan2
- OSBPL9 | c.1482T>A p.F494L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100543900; called by muse, mutect2, varscan2
- PCDHA1 | c.1320G>T p.R440S | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); catalogued as COSV100974423; called by muse, mutect2, varscan2
- PGLS | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV99395745; called by muse, mutect2, varscan2
- PNMA8A | c.56T>G p.V19G | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV100562405; called by muse, mutect2
- PRG4 | c.3506A>T p.Y1169F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100798285; called by muse, mutect2, varscan2
- PRICKLE2 | c.691T>G p.F231V (on ENST00000295902; = p.F175V on NM_198859.4) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99897834; called by muse, mutect2
- QSER1 | c.1280C>A p.S427* (on ENST00000399302; = p.S556* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV101234942; called by muse, mutect2, varscan2
- RAB27B | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772473656, COSV50494544; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1524T>G p.N508K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV99217236; called by muse, mutect2, varscan2
- RBM26 | c.1795A>T p.I599F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99936441; called by muse, mutect2, varscan2
- RFX7 | c.449T>C p.F150S (on ENST00000559447 / NM_001368074.1; = p.F247S on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100429193; called by muse, mutect2, varscan2
- RPAIN | c.412_413insT p.P138Lfs*29 | Frame Shift Ins (INS) | VAF 19/66 reads (29%) | catalogued as COSV100506888; called by mutect2, pindel, varscan2
- RPL3 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs565234105, COSV99335250; called by muse, mutect2, varscan2
- SEC14L4 | c.102T>G p.D34E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99743256; called by muse, mutect2, varscan2
- SLC44A2 | c.1823T>A p.L608Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100213393; called by muse, mutect2, varscan2
- SLITRK4 | c.2413G>T p.E805* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100567454; called by muse, mutect2, varscan2
- SYNE2 | c.11794G>C p.V3932L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV100648273; called by mutect2, varscan2
- SYT4 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.01); catalogued as rs1471484489, COSV54898438; called by muse, mutect2
- TRIP12 | c.5586G>A p.L1862= | Splice Region (SNP) | VAF 42/147 reads (29%) | catalogued as COSV99390778; called by muse, mutect2, varscan2
- TTLL1 | c.1198C>A p.Q400K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV99840502; called by muse, mutect2, varscan2
- U2SURP | c.2452T>A p.S818T | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV101204546; called by muse, mutect2, varscan2
- ULK2 | c.2885A>G p.E962G | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100860933; called by muse, mutect2, varscan2
- VPS37A | c.1075A>G p.I359V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.8); catalogued as COSV100249024; called by muse, mutect2
- WDR91 | c.965A>C p.E322A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.62); catalogued as COSV100615799, COSV60369279; called by muse, mutect2, varscan2
- ZC3HAV1 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV99648941; called by muse, mutect2, varscan2
- ZKSCAN1 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs774644217, COSV60875437; called by muse, mutect2, varscan2
- ZNF142 | c.1384T>G p.F462V (on ENST00000411696 / NM_001379660.1; = p.F262V on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1370762115, COSV101376978; called by muse, mutect2, varscan2
- ABCA13 | c.12253_12255dup p.L4085dup | In Frame Ins (INS) | VAF 11/106 reads (10%) | called by mutect2, pindel
- DOCK3 | c.3905_3909del p.N1302Rfs*23 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- ITPR1 | c.4433_4436del p.Y1478Sfs*6 (on ENST00000354582; = p.Y1463Sfs*6 on NM_002222.7) | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- LVRN | c.1286_1287del p.N429Mfs*16 | Frame Shift Del (DEL) | VAF 18/179 reads (10%) | called by mutect2, varscan2
- NONO | c.1265_1270del p.D422_T424delinsA | In Frame Del (DEL) | VAF 12/27 reads (44%) | called by mutect2, pindel, varscan2
- NPEPPS | c.1529_1531del p.A510del | In Frame Del (DEL) | VAF 29/83 reads (35%) | called by mutect2, pindel, varscan2
- PBRM1 | c.2727del p.K909Nfs*6 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- RPGRIP1L | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPART | c.75del p.L25Ffs*7 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- TCTN2 | c.1484del p.N495Mfs*18 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- TMEM203 | c.158dup p.F54Lfs*4 | Frame Shift Ins (INS) | VAF 9/96 reads (9%) | called by mutect2, pindel, varscan2
- TRAM2 | c.212_217del p.G71_K73delinsE | In Frame Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- UTRN | c.3919dup p.I1307Nfs*3 | Frame Shift Ins (INS) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- ABHD18 | c.864C>T p.V288= (on ENST00000398965 / NM_001039717.2; = p.V195= on NM_025097.2 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 52/213 reads (24%) | catalogued as rs772970028, COSV101180836; called by muse, mutect2, varscan2
- APOL6 | c.489T>C p.Y163= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs570906528, COSV101291010; called by muse, mutect2, varscan2
- C1orf109 | c.190C>A p.R64= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV100523703; called by muse, mutect2, varscan2
- CUL5 | c.324A>T p.P108= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV101263730, COSV67609935; called by muse, mutect2, varscan2
- ESD | c.831T>G p.A277= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV101099211; called by muse, mutect2, varscan2
- EXOC7 | c.813G>A p.T271= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV58741906, COSV58746086; called by muse, mutect2
- IGKV1D-13 | c.237G>T p.G79= | Silent (SNP) | VAF 29/117 reads (25%) | called by muse, mutect2, varscan2
- ITGAM | c.945G>T p.V315= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99792926; called by muse, mutect2, varscan2
- MINK1 | c.3105C>A p.G1035= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV99545222; called by muse, mutect2, varscan2
- MTR | c.969C>T p.C323= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100856243; called by muse, mutect2
- NBEAL1 | c.4974T>G p.P1658= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV101495762; called by muse, mutect2, varscan2
- NCKAP1L | c.2940T>C p.I980= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV53203527, COSV99515505; called by muse, mutect2, varscan2
- POLA2 | c.1227T>A p.I409= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99641211; called by muse, mutect2, varscan2
- SYT4 | c.336T>C p.P112= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99674222; called by muse, mutect2
- TAF7L | c.789T>C p.N263= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as rs140762002, COSV100229619; called by muse, mutect2, varscan2
- TANK | c.957C>A p.I319= | Silent (SNP) | VAF 42/196 reads (21%) | catalogued as COSV99376419; called by muse, mutect2, varscan2
- AL590867.2 | n.33del | RNA (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- H3-3B | c.-1A>T | 5'UTR (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99638116; called by muse, mutect2, varscan2
- IGKV1-13 | n.238G>T | RNA (SNP) | VAF 28/276 reads (10%) | called by muse, mutect2, varscan2
- LRRC55 | c.-14G>A | 5'UTR (SNP) | VAF 22/74 reads (30%) | catalogued as COSV101546764; called by muse, mutect2, varscan2
- NCOA7 | c.2245-1620A>G | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, varscan2
